Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3C6, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3C6-06A (Metastatic).

[page 1 of 2]
Redacted :W ADDENDUM SECTION *****

DIAGNOSIS

Patient ID -

(A) LYMPH NODES, RIGH INGUINAL, TIL PROTOCOL, DISSECTION:
METASTATIC EPITHELIOID NEOPLASM TO FIBROADIPOSE TISSUE.
Largest tumor deposit size: 50 x 40 mm.
Ten lymph nodes, melanoma is not identified (0/10)

(B) RIGHT ILIAC AND OBTURATOR CONTENTS, DISSECTION:
METASTATIC EPITHELIOID NEOPLASM TO ONE OF FOURLYMPH NODES (1 / 4).
Largest tumor deposit size: 2.0 x 1.0 mm.
Location: Subcapsular
Extracapsular extension: Not identified

Melanin pigment is not readily identified. An immunohistochemical study will be performed to try to confirm the diagnosis of metastatic melanoma and an addendum report will follow.

GROSS DESCRIPTION

(A) RIGHT INGUINAL CONTENTS TIL PROTOCOL - Received sterile and processed in the sterile hood for TIL protocol studies is a 23.0 x 8.0 x 2.8 cm unoriented portion of fibroadipose tissue partly surfaced by a 23.0 x 1.2 cm ellipse of pale tan, wrinkled skin. Specimen is sectioned to reveal a 5.0 x 4.0 x 3.0 cm tan, firm mass with tan, rubbery, lobulated cut surfaces that grossly comes to within 1.0 cm from the skin surface. The remainder of the adipose tissue is dissected to reveal ten possible lymph nodes ranging from 0.3 x 0.2 x 0.2 cm - 2.6 x 1.6 x 1.1 cm. The majority of the mass is given to TIL protocol and a portion has been given to tumor bank for research purposes.

SECTION CODE: A1, representative section of mass to skin; A2-A4, remainder of mass; A5, two possible lymph nodes; A6, two possible lymph nodes; A7, one possible lymph node, bisected; A8, one possible lymph node, serially sectioned; A9, one possible lymph node, serially sectioned; A10, one lymph node, serially sectioned; A11, A12, one possible lymph node, serially sectioned; A13, A14, one possible lymph node, serially sectioned.

(B) RIGHT ILIAC AND OBTURATOR CONTENTS - A 6.0 x 4.2 x 1.0 cm portion of fibroadipose tissue which yields five possible lymph nodes ranging from 0.8 - 8.0 cm in greatest dimension. The lymph nodes are submitted entirely.

SECTION CODE: B1, two lymph nodes; B2, one lymph node; B3, B4, one lymph node, serially sectioned; B5-B9, one lymph node, serially sectioned.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

T-C4000, M-87206, M-87206

Some tests reported here may have been developed and performance characteristics determined by I specifically cleared or approved by the U.S. Food and Drug Administration "

Entire report and diagnosis completed by:

These tests have not been

Start of ADDENDUM

[page 2 of 2]
ADDENDUM

This modified report is being issued to report special studies/IHC/Molecular studies and to include an additional, negative lymph node in specimen B.

Addendum completed by ' _____'

(A) LYMPH NODES, RIGHT INGUINAL, TIL PROTOCOL, DISSECTION:

METASTATIC MELANOMA TO FIBROADIPOSE TISSUE. (SEE COMMENT)

Largest tumor deposit size: 50 x 40 mm.

Ten lymph nodes, melanoma is not identified (0/10).

(B) RIGHT ILIAC AND OBTURATOR CONTENTS, DISSECTION:

METASTATIC MELANOMA TO ONE OF FIVE LYMPH NODES (1/5). (SEE COMMENT)

Largest tumor deposit size: 2.0 x 1.0 mm.

Location: Subcapsular.

Extracapsular extension: Not Identified.

COMMENT

Sections show metastatic melanoma involving adipose tissue; residual lymph node is not identified in this area. In part A, an immunohistochemical study performed here reveals that the tumor cells are positive with an anti-melanocytic cocktail (HMB45, anti-MART1, and anti-tyrosinase). This result supports the above diagnosis.

In part B, the tumor in the lymph node is histologically similar to the tumor in part A. This supports the above diagnosis.

Case discussed with Dr. : _____

Entire report and diagnosis completed by: _____

-----END OF REPORT-----

Source: NCI Genomic Data Commons file e469aa69-4d2f-4612-ae50-dca062954471 (TCGA-D3-A3C6.FAA72A58-CAB5-45ED-8727-9D9811AE0FA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).